Somatic mutation profile of tumor specimen 0DB2B7 from CCDI case PBBKTD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,273 days).
Specimen 0DB2B7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 711a5915-3881-4922-9690-8397730d416d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB2AO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38b74cc5-85a9-4b17-a5f3-7e96e4adc82c

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 42/665 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs762774245, COSV53354251; called by muse, mutect2
- CALR | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 177/1098 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57118591, COSV57126291; called by muse, mutect2, varscan2
- CAPN12 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 89/496 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.32); catalogued as rs781673043, COSV61016954; called by muse, mutect2, varscan2
- CD74 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 119/439 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1158850714, COSV50532603; called by muse, mutect2, varscan2
- GDF15 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 172/517 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.058); catalogued as rs942188038, COSV53250781; called by muse, mutect2, varscan2
- NOXA1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 148/966 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as rs550567027, COSV104418790; called by muse, mutect2, varscan2
- PIK3CA | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 108/490 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.314); catalogued as COSV56017486; called by muse, mutect2, varscan2
- ANKRD62 | c.1931A>G p.Q644R | Missense Mutation (SNP) | VAF 214/389 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- C1QL4 | c.387C>A p.D129E | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GSE1 | c.2444G>C p.R815P | Missense Mutation (SNP) | VAF 68/1021 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- LRP4 | c.5303C>T p.S1768F | Missense Mutation (SNP) | VAF 671/761 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ANKRD11 | c.6660G>A p.A2220= | Silent (SNP) | VAF 305/591 reads (52%) | catalogued as rs1274713579; called by muse, mutect2, varscan2
- CROCC2 | c.162G>T p.S54= | Silent (SNP) | VAF 249/560 reads (44%) | called by muse, mutect2, varscan2
- GSE1 | c.2445G>C p.R815= | Silent (SNP) | VAF 68/1018 reads (7%) | called by muse, mutect2
- KIT | c.1485C>T p.N495= | Silent (SNP) | VAF 115/641 reads (18%) | catalogued as rs775498908, COSV55422798; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC3B | c.570C>T p.N190= | Silent (SNP) | VAF 135/528 reads (26%) | catalogued as rs375239096; called by muse, mutect2, varscan2
- OR2AG2 | c.744C>T p.V248= | Silent (SNP) | VAF 266/592 reads (45%) | catalogued as rs769499432, COSV58456153; called by muse, mutect2, varscan2
- OR4Q3 | c.495T>A p.S165= | Silent (SNP) | VAF 114/692 reads (16%) | called by muse, mutect2, varscan2
- TPRN | c.537G>T p.A179= | Silent (SNP) | VAF 41/170 reads (24%) | catalogued as rs1281710603; called by muse, mutect2, varscan2
- C9orf85 | c.323+1277A>G | Intron (SNP) | VAF 6/103 reads (6%) | catalogued as rs1446441319, COSV58253961; called by muse, mutect2
- CALM3 | chr19:46601004 G>T | 5'Flank (SNP) | VAF 23/195 reads (12%) | called by muse, mutect2, varscan2
- CLEC4G | c.220+77G>A | Intron (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
